Surgical pathology report (de-identified scan), TCGA case TCGA-24-1553, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1553-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

FINAL WITH ADDENDUM

24-1553
* Converted Case * This report may not match the original report format

Patient Name: [REDACTED]

Address: [REDACTED]

Gender: [REDACTED]

DOB: [REDACTED]

Service: [REDACTED]

Location: [REDACTED]

MRN: [REDACTED]

Hospital #: [REDACTED]

Patient Type: [REDACTED]

Accession #: [REDACTED]

Taken: [REDACTED]

Received: [REDACTED]

Accessioned: [REDACTED]

Reported: [REDACTED]

Physician(s): [REDACTED]

DIAGNOSIS:

OVARY, LEFT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA OF MIXED
EPITHELIAL TYPE (SEE COMMENT)

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA

OVARY, RIGHT, SALPINGO-OOPHORECTOMY

- POORLY DIFFERENTIATED ADENOCARCINOMA OF MIXED
EPITHELIAL TYPE (SEE COMMENT)

FALLOPIAN TUBE, RIGHT, SALPINGO-OOPHORECTOMY

- METASTATIC ADENOCARCINOMA

SOFT TISSUE, RIGHT PAROVARIAN, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- FOCAL SQUAMOUS METAPLASIA
- METASTATIC ADENOCARCINOMA
INVOLVING DEEP CERVICAL SOFT
TISSUE

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- ATROPHIC ENDOMETRIUM

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA BY
EXTENSION FROM SEROSAL
IMPLANT
- LEIOMYOMA

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY

- METASTATIC ADENOCARCINOMA

OMENTUM, OMENTECTOMY - METASTATIC ADENOCARCINOMA, 2 MM IN GREATEST
DIMENSION

LYMPH NODE, PERIAORTIC, EXCISION (F51, X1)

- METASTATIC ADENOCARCINOMA

LYMPH NODE, PERIAORTIC, EXCISION - METASTATIC ADENOCARCINOMA

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion

Intraoperative Consultation:

FS, lymph node, periaortic, biopsy - Poorly differentiated carcinoma by

Microscopic Description and Comment:

Histologic sections from both ovaries show poorly differentiated adenocarcinoma of mixed epithelial type. The majority of the tumor is composed of solid nests with poorly differentiated, focally pleomorphic and multinucleated cells. In areas, definite papillary serous differentiation is identified. Other areas show back-to-back glandular structures diagnostic of endometrioid carcinoma. In many of these glandular areas, the central lumina are filled with mucin-type material. Metastatic adenocarcinoma with identical histologic features are present in both fallopian tubes, on the serosal surface of the uterus with extension into myometrium, in deep cervical soft tissue, and in right parovarian soft tissue. A single 2 mm. nodule of metastatic adenocarcinoma is present in the omentum. Both specimens of peri-aortic lymph node contain metastatic adenocarcinoma of identical histology.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Other: Mixed epithelial type - papillary serous and endometrioid (see comment)
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Tumor DOES invade the adjacent fallopian tube.
9. Tumor DOES invade the pelvic soft tissue.
10. Tumor involvement of the pelvic peritoneum CANNOT BE EVALUATED.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
13. The maximum dimension of tumor implants outside the true pelvis is 0.2 cm.
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are PRESENT.
17. The total number of regional lymph nodes examined is 1.
18. The total number of metastatically-involved regional lymph nodes is 1.

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Extranodal extension by tumor metastases is PRESENT

19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3b	IIIB	Macroscopic peritoneal metastasis beyond true pelvis, with no implant greater than 2 cm in maximum dimension.

THE REGIONAL LYMPH NODES are classified as:

N1 (Nodes contain metastatic tumor)

THE STATUS OF DISTANT TUMOR SITES is classified as:

MX (Status cannot be assessed)

20. The FINAL AJCC/FIGO STAGE IS:

AJCC SCHEME	FIGO SCHEME
X	Insufficient data to assign stage

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

History:

The patient is a [REDACTED] with a pelvic mass. Operative procedure: EUA, adhesiolysis, TAH-BSO, omentectomy.

Specimen(s) Received:

A: LYMPH NODE, BIOPSY, FS1-LYMPH NODE, PERIAORTI
B: LYMPH NODE, BIOPSY, X1-LYMPH NODE, PERIAORTIC
C: LYMNOD (Unrecognized part code), LYMPH NODE, PERIAORTIC
D: OVARY, OVARY/OVARIAN MASS, LEFT OVARY
E: UTERUS, UTERUS/HYSTERECTOMY [REDACTED] UTERUS, CERVIX, RIGHT TUB
F: OMENT (Unrecognized part code), OMENTUM

Gross Description:

The specimens are received in six containers of formalin, each labelled with the patient's name. The first is labelled "FS." It contains two fragments of white-tan tissue measuring 2.5 x 2.0 x 0.2 cm in aggregate. [REDACTED]

The second container is labelled "X, periaortic lymph node." It contains a single piece of tan-white tissue measuring 2.5 x 1.7 x 0.6 cm. [REDACTED]

The third container is labelled "periaortic lymph node." It contains three fragments of white-tan tissue measuring 5 x 3.5 x 3.5 cm in aggregate. Sections show nodular white-tan tissue with focal yellow areas. [REDACTED]

The third container is labelled "left ovary." It contains an ovary measuring 8.7 x 6.5 x 4.8 cm. The serosal surface is smooth, white-tan with a small amount of attached soft tissue. No fallopian tube is seen grossly. Sections show a single serous filled cyst measuring 4.0 cm in diameter with a smooth lining. On either side of the cyst is firm, yellow-white-tan nodular tissue grossly consistent with tumor. Residual ovarian tissue appears compressed along one edge. [REDACTED]

The next container is labelled "uterus, cervix, right tube and ovary." It contains a specimen consisting of uterus, right ovary and fallopian tube, and a large amount of soft tissue adherent to the right ovary and posterior uterus. The entire specimen weighs 480 grams. The uterus measures 10.0 cm superior to inferior x 4.0 cm cornu to cornu x 3.7 cm anterior to posterior. The left fallopian tube is also identified in the specimen measuring 5.0 cm in length and 0.5 cm in diameter. The distal end shows no fimbriae and is contiguous with the soft tissue mass. The left fallopian tube measures 11 cm in length x 0.5 cm in diameter. A fimbriated end is apparent and grossly involved by tumor. The

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

right ovary measures 5.5 x 4.0 x 3.0 cm. The superior serosal surface is smooth but the inferior portion of the ovary is contiguous with the attached soft tissue. The attached soft tissue measures 12 x 9 x 8 cm and is diffusely involved by white-yellow-tan tumor with some focal hemorrhage and fat necrosis. The cervix measures 3 x 2.2 x 3.5 cm and appears grossly unremarkable. The endometrium measures 0.1 to 0.2 cm in thickness and also appears grossly unremarkable. The myometrium measures 1.8 cm in thickness. Sections through the posterior myometrium show invasion of tumor from the serosal surface into the serosal one-third of the myometrium. Labelled C1, anterior cervix; C2, posterior cervix; E1, anterior endomyometrium; E2, posterior endomyometrium; LT left fallopian tube; RT, right fallopian tube; RO1, RO2, right ovary; ST1 and ST2, soft tissue with tumor.

The fifth container is labelled "omentum." It contains a sheet of fibroadipose tissue measuring 35 x 12 x 1.0 cm. A single, firm, white nodule measuring 0.2 cm in diameter, grossly suspicious for tumor is present. The remainder of the tissue is unremarkable. Labelled O1, omentum with suspicious nodule; O2-O5, unremarkable omentum.

Addenda/Procedures

Addendum Ordered:

Status: Signed Out

Addendum Complete:

By:

Addendum Signed Out:

Addendum Comment

An immunohistochemical stain for Her2neu (*c-erbB-2*) was performed on a representative tissue section from block using a polyclonal antibody-based assay (HercepTest). No immunoreactivity for this oncoprotein was observed in carcinoma cells.

Interpretation: negative for *c-erbB-2*

Addendum Ordered:

Status: Signed Out

Addendum Complete:

By:

Addendum Signed Out:

Addendum Comment

An immunohistochemical stain for C-kit performed on tissue sections from blocks E/RO1 and E2 showed no significant immunoreactivity in the adenocarcinoma.

Source: NCI Genomic Data Commons file bd1da4d0-e508-4ecf-a80c-3b93ea9618c1 (TCGA-24-1553.5ABE7782-CA53-4ADD-9A9A-01955859420B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).